Gene-level copy-number profile of tumor specimen ALCH-B2AQ-TTP1-B from ALCHEMIST case ALCH-B2AQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.7 years (20,697 days).
Specimen ALCH-B2AQ-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 048288de-047a-41f7-8f94-1e7e96a43030.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2AQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/aa7c1cd4-79af-4001-a085-3b86eddffe65

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 109; copy number 1: 8,499; copy number 2: 42,155; copy number 3: 7,044; copy number 4: 490; copy number 5: 41; copy number 6: 1; copy number 7: 1; copy number 8: 1; copy number 10: 34; copy number 19: 1; copy number 25: 2; copy number 27: 6.

Homozygous deletions (total copy number 0; autosomes only): 105 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:904,834–959,309, 6 genes: AL645608.6, AL645608.2, AL645608.4, LINC02593, SAMD11, NOC2L.
- chr1:975,204–982,093, 1 gene (within-gene range 0–4): PERM1.
- chr2:86,907,953–87,013,976, 3 genes (within-gene range 0–3): RGPD1, WBP1P1, NDUFB4P5.
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr7:1,428,465–1,504,389, 4 genes: MICALL2, AC102953.1, AC102953.2, INTS1.
- chr7:1,530,702–1,560,821, 2 genes: MAFK, TMEM184A.
- chr7:73,985,992–73,988,767, 1 gene: AC099398.1.
- chr9:136,483,495–136,486,067, 1 gene (within-gene range 0–2): C9orf163.
- chr9:136,759,634–136,766,255, 1 gene: LCN15.
- chr10:133,278,630–133,312,337, 2 genes (within-gene range 0–2): TUBGCP2, AL360181.2.
- chr11:417,933–442,011, 2 genes: ANO9, RN7SL838P.
- chr14:104,085,686–104,180,894, 5 genes: ASPG, MIR203A, MIR203B, AL359399.1, KIF26A.
- chr15:41,825,099–41,848,155, 4 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B.
- chr15:85,958,717–85,958,971, 1 gene: AC104229.1.
- chr16:629,239–719,655, 18 genes (within-gene range 0–2): WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1, METRN.
- chr16:760,734–768,865, 1 gene: MSLN.
- chr16:2,140,803–2,214,840, 10 genes: RAB26, SNHG19, SNORD60, AC009065.9, TRAF7, CASKIN1, MLST8, BRICD5, PGP, AC009065.7.
- chr16:54,930,865–54,954,665, 3 genes: IRX5, AC106738.1, AC106738.2.
- chr17:18,497,095–18,521,252, 2 genes: NOS2P2, USP32P2.
- chr17:81,197,393–81,200,288, 1 gene (within-gene range 0–1): AC027601.2.
- chr18:79,470,120–79,516,057, 3 genes (within-gene range 0–1): AC018445.1, AC018445.4, AC018445.2.
- chr19:637,105–637,537, 1 gene: AC004449.1.
- chr19:647,526–663,233, 1 gene: RNF126.
- chr19:2,096,429–2,099,593, 1 gene (within-gene range 0–1): IZUMO4.
- chr19:2,163,933–2,248,655, 6 genes (within-gene range 0–3): DOT1L, AC004490.1, PLEKHJ1, MIR1227, MIR6789, SF3A2.
- chr19:2,269,525–2,341,172, 6 genes (within-gene range 0–2): AC005258.1, PEAK3, LINGO3, AC104530.1, AC005258.2, LSM7.
- chr19:3,118,665–3,131,398, 3 genes (within-gene range 0–2): AC005262.2, KF456478.1, AC005262.1.
- chr20:62,352,995–62,356,480, 1 gene (within-gene range 0–1): LAMA5-AS1.
- chr21:14,007,134–14,020,725, 2 genes: PPP6R2P1, FRG2MP.
- chr21:43,358,147–43,366,566, 2 genes: LINC01679, AP001046.1.
- chr21:43,461,960–43,479,534, 2 genes: LINC00313, AP001048.1.
- chr21:44,300,051–44,340,470, 5 genes: PFKL, AP001062.3, CFAP410, AP001062.1, AP001062.2.
- chr22:46,244,011–46,263,343, 2 genes: CDPF1, PKDREJ.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 87 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,997,206–10,016,021, 1 gene, copy number 5: RBP7.
- chr6:50,587,607–50,637,205, 1 gene, copy number 5: AL135908.1.
- chr7:1,620,654–1,621,405, 1 gene, copy number 6: AC074389.2.
- chr7:16,916,359–17,346,152, 1 gene, copy number 5 (within-gene range 3–5): AHR.
- chr7:16,970,320–17,299,368, 1 gene, copy number 5 (within-gene range 3–5): AC073332.1.
- chr7:75,281,243–75,416,787, 9 genes, copy number 7–27 (within-gene range 2–27): SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, AC211486.1, TRIM73, NSUN5P1.
- chr12:64,759,484–66,170,072, 34 genes, copy number 10 (within-gene range 4–10): TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4.
- chr19:639,879–644,371, 1 gene, copy number 8: FGF22.
- chr20:18,059,493–19,056,796, 36 genes, copy number 5: AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1.
- chr20:63,843,436–63,843,915, 1 gene, copy number 5: C20orf181.
- chr21:43,414,483–43,427,131, 1 gene, copy number 19: SIK1.

Autosomal genes at a single copy (total copy number 1): 8,499. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
